Somatic mutation profile of tumor specimen C3L-02345-02 (aliquot CPT0113990009) from CPTAC case C3L-02345, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 61.8 years (22,572 days).
Specimen C3L-02345-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3a376a1-6ab2-43e7-a664-476316156cca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02345-31 (Blood Derived Normal), aliquot CPT0115310002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/204054f2-1d6a-40f1-92b2-1d67e0e109ab

The open-access MAF lists 324 somatic variants for this specimen: 207 protein-altering or splice-affecting, 76 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 178, Silent 76, Intron 21, Nonsense Mutation 12, Frame Shift Del 9, 3'UTR 6, 5'UTR 6, RNA 6, Splice Region 4, Nonstop Mutation 1, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 116/328 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- STK11 | c.169dup p.E57Gfs*106 | Frame Shift Ins (INS) | VAF 53/273 reads (19%) | catalogued as rs121913319; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC9 | c.1724T>A p.L575Q | Missense Mutation (SNP) | VAF 127/341 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53972642; called by muse, mutect2, varscan2
- ACAN | c.6478G>T p.E2160* | Nonsense Mutation (SNP) | VAF 48/237 reads (20%) | catalogued as COSV100719051; called by muse, mutect2, varscan2
- ACTN2 | c.1080C>A p.F360L | Missense Mutation (SNP) | VAF 46/449 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63975022; called by muse, mutect2, varscan2
- ANKFN1 | c.1546G>T p.A516S | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV59447607; called by muse, mutect2, varscan2
- BRCA1 | c.5576C>T p.P1859L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); catalogued as COSV100524823; called by muse, mutect2, varscan2
- CBL | c.1096G>T p.E366* | Nonsense Mutation (SNP) | VAF 36/158 reads (23%) | catalogued as COSV50657369, COSV50665310; called by muse, varscan2
- CCDC178 | c.1250C>A p.A417E | Missense Mutation (SNP) | VAF 23/149 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as rs753939150; called by muse, mutect2, varscan2
- CEP170 | c.2999G>T p.G1000V | Missense Mutation (SNP) | VAF 27/442 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV60509303; called by muse, mutect2
- COL11A1 | c.2295G>T p.K765N | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62197657, COSV62201337; called by muse, mutect2, varscan2
- COL8A2 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.886); catalogued as rs1557738510; called by muse, mutect2, varscan2
- COL9A3 | c.685-1G>T p.X229_splice | Splice Site (SNP) | VAF 71/296 reads (24%) | catalogued as rs866697463; called by muse, mutect2, varscan2
- COX8C | c.107A>T p.Q36L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.506); catalogued as rs1198380771; called by muse, mutect2, varscan2
- CSMD3 | c.1624G>T p.V542L (on ENST00000297405 / NM_001363185.1; = p.V438L on NM_052900.3) | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.077); catalogued as rs1407449531, COSV52289013; called by muse, mutect2, varscan2
- CYLD | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 59/202 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.452); catalogued as rs757203445; called by muse, mutect2, varscan2
- DNHD1 | c.8500C>T p.P2834S | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.02); catalogued as rs1304074747; called by muse, mutect2, varscan2
- DUOX1 | c.2255G>A p.R752K | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761250202; called by muse, mutect2, varscan2
- EPHA5 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as rs1198864954, COSV56656026; called by muse, mutect2, varscan2
- FTMT | c.130G>A p.A44T | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs572583166; called by muse, mutect2, varscan2
- GPR55 | c.80A>G p.H27R | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.101); catalogued as rs1194338874, COSV67408954; called by muse, mutect2, varscan2
- GRIN3A | c.1938C>A p.S646R | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1471289479; called by muse, mutect2
- HAUS7 | c.686C>A p.A229D | Missense Mutation (SNP) | VAF 49/192 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); catalogued as COSV57848396; called by muse, mutect2, varscan2
- HUWE1 | c.3601G>A p.A1201T | Missense Mutation (SNP) | VAF 47/349 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV99474106; called by muse, mutect2, varscan2
- IFNAR1 | c.703A>T p.I235L | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.024); catalogued as COSV54251554, COSV54251955; called by muse, mutect2, varscan2
- IGSF22 | c.1855G>A p.V619M | Missense Mutation (SNP) | VAF 35/146 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs367726129; called by muse, mutect2, varscan2
- KLC2 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as rs140962519; called by muse, mutect2, varscan2
- KRT222 | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.079); catalogued as rs1555607515; called by muse, mutect2, varscan2
- LAIR2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763891376, COSV56621743; called by muse, mutect2, varscan2
- LAMB4 | c.2537G>T p.R846L | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.067); catalogued as rs371953336; called by muse, mutect2, varscan2
- LHX4 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 28/326 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as rs752455651, CM1210489, COSV55374671; called by muse, mutect2
- MAGEB5 | c.179G>T p.R60L | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs754656027, COSV66869124; called by muse, mutect2, varscan2
- MARCO | c.1301G>T p.R434L | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59051526; called by muse, mutect2, varscan2
- MYH7B | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.473); catalogued as rs1569034840, COSV99483237; called by muse, mutect2
- MYO16 | c.4522G>A p.E1508K | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1261639503; called by mutect2, varscan2
- NF1 | c.1105C>T p.Q369* | Nonsense Mutation (SNP) | VAF 80/384 reads (21%) | catalogued as CM1411378, COSV62199205; called by muse, mutect2, varscan2
- OR1E2 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 54/282 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50265539; called by muse, mutect2, varscan2
- OR4D9 | c.163C>A p.L55I | Missense Mutation (SNP) | VAF 46/219 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781430847; called by muse, mutect2, varscan2
- OTOA | c.1577G>A p.G526E (on ENST00000286149; = p.G512E on NM_144672.4) | Missense Mutation (SNP) | VAF 62/307 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.938); catalogued as COSV99623854; called by muse, mutect2, varscan2
- OTOL1 | c.788G>T p.G263V | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60008267; called by muse, mutect2, varscan2
- PCDHB5 | c.928G>T p.A310S | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.027); catalogued as COSV50665143; called by muse, mutect2, varscan2
- PIKFYVE | c.3427G>T p.G1143C | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs1410039024; called by muse, mutect2, varscan2
- PNLIP | c.14G>C p.W5S | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV65041884; called by muse, mutect2, varscan2
- PTCH1 | c.1728G>T p.Q576H | Missense Mutation (SNP) | VAF 28/364 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100107995; called by muse, mutect2
- RCBTB2 | c.472G>C p.A158P | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs775002328; called by muse, mutect2, varscan2
- RGPD4 | c.5123C>A p.A1708D | Missense Mutation (SNP) | VAF 79/494 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as COSV100736685; called by muse, mutect2, varscan2
- RXFP1 | c.1919G>T p.C640F | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749519361; called by muse, mutect2, varscan2
- SCRN1 | c.852G>T p.Q284H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.719); catalogued as COSV54129911; called by muse, mutect2, varscan2
- SEMA4A | c.1740C>A p.C580* | Nonsense Mutation (SNP) | VAF 18/188 reads (10%) | catalogued as rs754643343; called by muse, mutect2
- SLC26A7 | c.805G>T p.A269S | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as rs1393956142; called by muse, mutect2, varscan2
- SSTR2 | c.460A>T p.R154W | Missense Mutation (SNP) | VAF 22/234 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59535211; called by muse, mutect2
- SYN1 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.053); catalogued as COSV99927637; called by muse, mutect2, varscan2
- TMEM132A | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV50006941; called by muse, mutect2, varscan2
- TMEM74 | c.621C>A p.N207K | Missense Mutation (SNP) | VAF 40/291 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs1439704883; called by muse, mutect2, varscan2
- TMPRSS15 | c.939del p.T314Pfs*4 | Frame Shift Del (DEL) | VAF 42/240 reads (18%) | catalogued as rs1173449918; called by mutect2, pindel, varscan2
- TRIML1 | c.713G>T p.S238I | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as rs779122084; called by muse, mutect2, varscan2
- TSKS | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as rs745628160; called by muse, mutect2, varscan2
- VHLL | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 103/322 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100372662; called by muse, mutect2, varscan2
- VMP1 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as rs1171013928, COSV99230674; called by muse, mutect2
- ZBP1 | c.712G>T p.D238Y | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV59060525; called by muse, mutect2, varscan2
- ZMYM4 | c.4568G>A p.R1523H | Missense Mutation (SNP) | VAF 32/306 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58911070, COSV58913093; called by muse, mutect2, varscan2
- ZNF264 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs1418529032; called by muse, mutect2, varscan2
- ZNF324B | c.524G>T p.R175M | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.628); catalogued as rs1188058304; called by muse, mutect2, varscan2
- ZNF333 | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1192121807; called by muse, mutect2, varscan2
- ZNF735 | c.571G>A p.G191S | Missense Mutation (SNP) | VAF 43/208 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.843); catalogued as rs1161060481; called by muse, mutect2, varscan2
- AASDH | c.1661A>G p.D554G | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ABCA7 | c.1817G>T p.S606I | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ABCB7 | c.496G>T p.D166Y (on ENST00000373394 / NM_001271696.3; = p.D167Y on NM_004299.6) | Missense Mutation (SNP) | VAF 82/416 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AFF2 | c.1707G>C p.Q569H | Missense Mutation (SNP) | VAF 52/262 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.961); called by muse, varscan2
- AIFM1 | c.1112C>G p.S371C | Missense Mutation (SNP) | VAF 79/420 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ALLC | c.669A>C p.G223= | Splice Region (SNP) | VAF 23/174 reads (13%) | called by muse, mutect2, varscan2
- AMELX | c.483G>A p.M161I | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT tolerated (0.99); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMER1 | c.2518G>T p.A840S | Missense Mutation (SNP) | VAF 80/402 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); called by muse, varscan2
- ANKRD36B | c.742C>A p.L248I | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- ARMC6 | c.1148G>T p.S383I (on ENST00000392336; = p.S358I on NM_033415.4) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- ARNTL | c.1099G>A p.E367K (on ENST00000403290 / NM_001297719.2; = p.E366K on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BCL11B | c.157C>A p.P53T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- C16orf82 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- C1QTNF4 | c.332G>T p.R111L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- CCDC136 | c.2884G>T p.E962* | Nonsense Mutation (SNP) | VAF 45/172 reads (26%) | called by muse, varscan2
- CCDC168 | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 30/214 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- CPXM2 | c.472C>A p.R158S | Missense Mutation (SNP) | VAF 44/312 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CRB2 | c.593C>G p.T198R | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- CRYBG2 | c.952G>T p.G318C | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CSF3 | c.208G>C p.A70P | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CTNND2 | c.296A>G p.E99G | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CYLC2 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.662); called by muse, mutect2
- CYLD | c.563A>T p.Q188L | Missense Mutation (SNP) | VAF 60/206 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DCAF12L1 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 48/228 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DEFB115 | c.146del p.C49Sfs*? | Frame Shift Del (DEL) | VAF 32/140 reads (23%) | called by mutect2, pindel, varscan2
- DLGAP4 | c.571G>T p.G191W | Missense Mutation (SNP) | VAF 54/265 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- DMRTA1 | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- DNAH5 | c.7470G>T p.W2490C | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPY19L1 | c.409del p.V137Lfs*26 | Frame Shift Del (DEL) | VAF 60/303 reads (20%) | called by mutect2, pindel, varscan2
- DQX1 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- DSG4 | c.1985G>A p.G662D | Missense Mutation (SNP) | VAF 73/525 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- DST | c.1185G>T p.R395S (on ENST00000361203 / NM_001374722.1; = p.R69S on NM_001723.6) | Missense Mutation (SNP) | VAF 84/362 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by mutect2, varscan2
- DTX3 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- DYSF | c.901T>A p.F301I | Missense Mutation (SNP) | VAF 60/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, varscan2
- FBXO34 | c.2029G>T p.G677C | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FOXI1 | c.923C>A p.P308H | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FRMPD2 | c.929G>T p.R310M | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- FSIP2 | c.15969T>G p.F5323L | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- FUS | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- GP2 | c.357G>T p.M119I | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GPHB5 | c.363del p.T122Lfs*? | Frame Shift Del (DEL) | VAF 18/117 reads (15%) | called by mutect2, pindel, varscan2
- GRIA2 | c.1256C>A p.T419N | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- GTF3C1 | c.664A>T p.I222F | Missense Mutation (SNP) | VAF 45/197 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HMX1 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- HTR5A | c.247G>T p.A83S | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HUWE1 | c.3352C>G p.P1118A | Missense Mutation (SNP) | VAF 73/256 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- IGIP | c.131G>T p.S44I | Missense Mutation (SNP) | VAF 53/274 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); called by muse, varscan2
- IKZF1 | c.49A>T p.S17C | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- IP6K3 | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- KCNA5 | c.1469C>A p.T490N | Missense Mutation (SNP) | VAF 86/195 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCND3 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- KCNH1 | c.120G>T p.W40C | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.9); called by muse, varscan2
- KHDRBS3 | c.576G>T p.L192F | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- KIF21B | c.3722C>A p.S1241Y | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- KLHL34 | c.1812C>A p.D604E | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- L2HGDH | c.703+8A>G | Splice Region (SNP) | VAF 37/217 reads (17%) | called by muse, mutect2, varscan2
- LCP2 | c.1053del p.M352* | Frame Shift Del (DEL) | VAF 55/254 reads (22%) | called by mutect2, pindel, varscan2
- LRP1B | c.8957A>T p.Y2986F | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LRRC8B | c.1202T>A p.L401H | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LTBP4 | c.695T>G p.V232G (on ENST00000308370 / NM_001042544.1; = p.V195G on NM_003573.2) | Missense Mutation (SNP) | VAF 65/306 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MAGEA6 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAST1 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 88/363 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- MED12 | c.3941G>T p.S1314I | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- MEIS2 | c.1098G>T p.M366I (on ENST00000561208 / NM_170675.5; = p.M346I on NM_002399.3) | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MRC1 | c.2961A>G p.I987M | Missense Mutation (SNP) | VAF 58/314 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MROH2A | c.840C>G p.I280M | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MXRA5 | c.6686A>G p.D2229G | Missense Mutation (SNP) | VAF 64/442 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NBEAL1 | c.3971T>C p.V1324A | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLGN4X | c.1607del p.P536Qfs*39 | Frame Shift Del (DEL) | VAF 86/300 reads (29%) | called by mutect2, pindel, varscan2
- NOX4 | c.665A>T p.H222L | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, varscan2
- NPAP1 | c.947C>A p.A316D | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- NPFFR2 | c.1162T>C p.S388P | Missense Mutation (SNP) | VAF 70/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- NUTM2A | c.758C>G p.P253R | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.631); called by mutect2, varscan2
- OCSTAMP | c.1382T>A p.L461Q | Missense Mutation (SNP) | VAF 69/316 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OGT | c.2073G>T p.Q691H | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- OR1L6 | c.863del p.F288Sfs*23 (on ENST00000373684; = p.F252Sfs*23 on NM_001004453.2) | Frame Shift Del (DEL) | VAF 26/140 reads (19%) | called by mutect2, pindel, varscan2
- OR2G6 | c.141del p.V48Yfs*38 | Frame Shift Del (DEL) | VAF 34/344 reads (10%) | called by mutect2, pindel
- OR2H2 | c.386A>T p.H129L | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- OR8H3 | c.937T>A p.*313Kext*? | Nonstop Mutation (SNP) | VAF 9/47 reads (19%) | called by muse, varscan2
- P2RY13 | c.151T>C p.Y51H | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PASD1 | c.1108A>T p.I370F | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.332); called by muse, mutect2, varscan2
- PCDH19 | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 89/386 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PCDHGA6 | c.1432G>C p.D478H | Missense Mutation (SNP) | VAF 63/343 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCLO | c.5456G>A p.R1819K | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PEG3 | c.3338G>T p.G1113V | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGAM4 | c.520del p.Q174Rfs*9 | Frame Shift Del (DEL) | VAF 57/318 reads (18%) | called by mutect2, pindel, varscan2
- PHF21B | c.622C>A p.P208T | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POU4F2 | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PROKR2 | c.383G>T p.C128F | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALYL | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAP1GAP | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 30/165 reads (18%) | called by muse, mutect2, varscan2
- REM1 | c.266C>G p.P89R | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- RIPK3 | c.1445_1447del p.S482_G483delinsC | In Frame Del (DEL) | VAF 35/212 reads (17%) | called by mutect2, pindel, varscan2
- RPUSD1 | c.-8+4G>C | Splice Region (SNP) | VAF 16/146 reads (11%) | called by muse, mutect2
- RUFY3 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RYR3 | c.8236T>A p.W2746R (on ENST00000389232; = p.W2747R on NM_001036.6) | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAGE1 | c.1617G>C p.R539S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- SHANK1 | c.3652G>T p.A1218S | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SHOX | c.689C>A p.P230Q | Missense Mutation (SNP) | VAF 135/396 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- SLC4A3 | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 33/148 reads (22%) | called by muse, mutect2, varscan2
- SLCO4A1 | c.1638+8G>T | Splice Region (SNP) | VAF 48/230 reads (21%) | called by muse, mutect2, varscan2
- SMC2 | c.260A>T p.D87V | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- SPANXN1 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 64/257 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- SPIDR | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPIN4 | c.49T>C p.Y17H | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ST3GAL5 | c.650C>T p.S217F (on ENST00000377332; = p.S257F on NM_003896.4) | Missense Mutation (SNP) | VAF 78/317 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- SUGP2 | c.2722G>T p.A908S | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.86); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYTL4 | c.912G>T p.M304I | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TANC2 | c.2822G>T p.R941L | Missense Mutation (SNP) | VAF 70/372 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.499); called by muse, mutect2, varscan2
- TBC1D30 | c.1467G>T p.M489I (on ENST00000542120; = p.M326I on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TCF15 | c.243G>C p.E81D | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TEX13C | c.1726C>A p.Q576K | Missense Mutation (SNP) | VAF 88/452 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, varscan2
- TEX35 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- TIGD1 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- TINAG | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMC2 | c.147G>T p.R49S | Missense Mutation (SNP) | VAF 91/379 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMC8 | c.1505T>A p.F502Y | Missense Mutation (SNP) | VAF 79/389 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- TMEM196 | c.40C>G p.L14V | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TP53BP1 | c.2026G>T p.G676* | Nonsense Mutation (SNP) | VAF 24/84 reads (29%) | called by muse, mutect2, varscan2
- TRDN | c.904C>A p.P302T | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TSGA13 | c.626C>A p.A209D | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); called by muse, mutect2
- TUBB2B | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 72/313 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TULP1 | c.844C>A p.P282T | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNDC2 | c.791C>A p.P264H (on ENST00000306084 / NM_001098529.2; = p.P197H on NM_032243.6) | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- UBE4B | c.3778C>T p.R1260W (on ENST00000343090 / NM_001105562.3; = p.R1131W on NM_006048.5) | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UGGT2 | c.2468A>C p.Y823S | Missense Mutation (SNP) | VAF 40/208 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- UPK1A | c.256C>A p.L86I | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- USP34 | c.3898C>T p.L1300F | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- VAV3 | c.447T>G p.D149E | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- VCPIP1 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VWA3A | c.3332A>T p.Y1111F | Missense Mutation (SNP) | VAF 59/313 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- WDR92 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 43/157 reads (27%) | called by muse, varscan2
- XK | c.773G>T p.C258F | Missense Mutation (SNP) | VAF 109/372 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZFHX3 | c.2935G>T p.V979L | Missense Mutation (SNP) | VAF 46/203 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ZIC5 | c.762C>A p.S254R | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZNF33B | c.1617C>G p.D539E | Missense Mutation (SNP) | VAF 45/200 reads (23%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- ZNF345 | c.526T>A p.C176S | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF420 | c.796C>G p.L266V | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ZNF611 | c.1684G>T p.G562* | Nonsense Mutation (SNP) | VAF 50/216 reads (23%) | called by muse, mutect2, varscan2
- ZNF630 | c.1308T>A p.C436* | Nonsense Mutation (SNP) | VAF 82/279 reads (29%) | called by muse, mutect2, varscan2
- ZNF669 | c.1229G>C p.R410T | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- ZNF81 | c.571A>C p.K191Q | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCA13 | c.9549C>A p.L3183= | Silent (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2
- ABCA13 | c.13692G>T p.S4564= | Silent (SNP) | VAF 33/180 reads (18%) | catalogued as COSV68946075; called by muse, mutect2, varscan2
- ACAN | c.1014C>A p.P338= | Silent (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- ACTL8 | c.195C>T p.Y65= | Silent (SNP) | VAF 35/290 reads (12%) | catalogued as rs1484915983; called by muse, mutect2, varscan2
- APOB | c.12024C>G p.T4008= | Silent (SNP) | VAF 67/274 reads (24%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.1737C>A p.A579= | Silent (SNP) | VAF 48/147 reads (33%) | called by muse, mutect2, varscan2
- ARL13A | c.360G>T p.V120= | Silent (SNP) | VAF 25/91 reads (27%) | called by muse, mutect2, varscan2
- ASB2 | c.411G>T p.L137= | Silent (SNP) | VAF 13/80 reads (16%) | called by muse, mutect2, varscan2
- ATP8B4 | c.3198C>T p.C1066= | Silent (SNP) | VAF 33/140 reads (24%) | called by muse, mutect2, varscan2
- B3GNT6 | c.558G>T p.L186= | Silent (SNP) | VAF 42/194 reads (22%) | called by muse, mutect2, varscan2
- BOLA1 | c.144G>T p.V48= | Silent (SNP) | VAF 33/155 reads (21%) | called by muse, mutect2, varscan2
- BRDT | c.2781G>T p.V927= | Silent (SNP) | VAF 28/150 reads (19%) | called by muse, mutect2, varscan2
- C1orf167 | c.2181C>A p.L727= | Silent (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- C2orf16 | c.1584G>A p.T528= | Silent (SNP) | VAF 31/300 reads (10%) | catalogued as COSV62675972; called by muse, mutect2
- C6 | c.1500A>T p.A500= | Silent (SNP) | VAF 51/309 reads (17%) | catalogued as COSV54709738; called by muse, mutect2, varscan2
- C8B | c.1188G>T p.L396= | Silent (SNP) | VAF 45/363 reads (12%) | catalogued as rs1260734950; called by muse, varscan2
- CAMTA2 | c.2322C>G p.L774= | Silent (SNP) | VAF 40/234 reads (17%) | called by muse, mutect2, varscan2
- CR2 | c.159T>C p.G53= | Silent (SNP) | VAF 26/446 reads (6%) | called by muse, mutect2
- CRYBB1 | c.507C>T p.D169= | Silent (SNP) | VAF 91/501 reads (18%) | catalogued as rs549883505, COSV53232290; called by muse, mutect2, varscan2
- DAGLA | c.939C>T p.P313= | Silent (SNP) | VAF 54/269 reads (20%) | catalogued as rs780344581; called by muse, mutect2, varscan2
- DNA2 | c.117G>T p.L39= | Silent (SNP) | VAF 45/200 reads (23%) | called by muse, mutect2, varscan2
- EN2 | c.831G>T p.L277= | Silent (SNP) | VAF 72/324 reads (22%) | called by muse, mutect2, varscan2
- ESR1 | c.807C>A p.R269= | Silent (SNP) | VAF 53/175 reads (30%) | called by muse, varscan2
- FAM47A | c.1719C>A p.P573= | Silent (SNP) | VAF 45/285 reads (16%) | called by muse, mutect2, varscan2
- FOXI1 | c.924C>A p.P308= | Silent (SNP) | VAF 19/94 reads (20%) | called by muse, mutect2, varscan2
- GPER1 | c.873C>A p.A291= | Silent (SNP) | VAF 32/138 reads (23%) | called by muse, mutect2, varscan2
- GRID2IP | c.270C>T p.G90= | Silent (SNP) | VAF 15/72 reads (21%) | called by muse, mutect2, varscan2
- H6PD | c.2064G>T p.L688= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- HEPH | c.1671G>T p.L557= (on ENST00000343002; = p.L290= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/315 reads (17%) | called by muse, mutect2, varscan2
- HERC2 | c.2553A>G p.E851= | Silent (SNP) | VAF 31/156 reads (20%) | called by muse, mutect2, varscan2
- HOXB6 | c.225G>T p.G75= | Silent (SNP) | VAF 25/135 reads (19%) | called by muse, mutect2, varscan2
- KCNQ3 | c.2610G>A p.K870= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as rs562384890; called by muse, varscan2
- LILRB1 | c.2049C>A p.S683= (on ENST00000427581; = p.S632= on NM_006669.6) | Silent (SNP) | VAF 40/243 reads (16%) | catalogued as COSV61116758; called by muse, mutect2, varscan2
- MAGEB17 | c.720G>T p.G240= | Silent (SNP) | VAF 54/163 reads (33%) | called by muse, mutect2, varscan2
- MEOX2 | c.219C>T p.H73= | Silent (SNP) | VAF 34/176 reads (19%) | catalogued as COSV100012552; called by muse, mutect2, varscan2
- MOCS3 | c.1167A>G p.L389= | Silent (SNP) | VAF 56/253 reads (22%) | called by muse, mutect2, varscan2
- MRPS33 | c.111T>C p.F37= | Silent (SNP) | VAF 97/428 reads (23%) | called by muse, mutect2, varscan2
- MUC17 | c.5133A>T p.S1711= | Silent (SNP) | VAF 23/88 reads (26%) | called by muse, mutect2, varscan2
- MUC2 | c.918G>C p.S306= | Silent (SNP) | VAF 9/138 reads (7%) | catalogued as rs377308143; called by muse, mutect2
- MYO16 | c.2844G>A p.S948= | Silent (SNP) | VAF 46/301 reads (15%) | catalogued as rs144060419; ClinVar: likely benign; called by muse, mutect2, varscan2
- MYT1L | c.927A>T p.G309= | Silent (SNP) | VAF 32/237 reads (14%) | called by muse, mutect2, varscan2
- NEU1 | c.273C>A p.L91= | Silent (SNP) | VAF 13/298 reads (4%) | catalogued as COSV57666726; called by muse, mutect2
- NINL | c.1368G>T p.A456= | Silent (SNP) | VAF 29/170 reads (17%) | catalogued as COSV99625550; called by muse, mutect2, varscan2
- OR4P4 | c.480C>A p.L160= | Silent (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- OR52N4 | c.141C>T p.L47= | Silent (SNP) | VAF 62/299 reads (21%) | called by muse, mutect2, varscan2
- OR5B3 | c.75C>A p.L25= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, varscan2
- OTX2 | c.753C>T p.N251= (on ENST00000408990 / NM_172337.3; = p.N259= on NM_021728.4) | Silent (SNP) | VAF 17/411 reads (4%) | called by muse, mutect2
- PCDHB12 | c.1710G>A p.A570= | Silent (SNP) | VAF 92/838 reads (11%) | catalogued as COSV99507090; called by muse, mutect2, varscan2
- PCDHGB7 | c.1386A>G p.P462= | Silent (SNP) | VAF 55/232 reads (24%) | called by muse, mutect2, varscan2
- PEG10 | c.954G>T p.A318= (on ENST00000482108 / NM_001040152.2; = p.G352W on NM_015068.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/156 reads (23%) | called by muse, varscan2
- PKD1L1 | c.456G>A p.R152= | Silent (SNP) | VAF 20/142 reads (14%) | catalogued as COSV99068869; called by muse, mutect2, varscan2
- PLEKHG5 | c.651C>T p.P217= (on ENST00000400915 / NM_001042663.3; = p.P180= on NM_020631.6) | Silent (SNP) | VAF 32/252 reads (13%) | catalogued as rs372624847, COSV100557079; called by muse, varscan2
- PLEKHO2 | c.1197G>A p.P399= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as rs768414225; called by muse, mutect2
- PTCRA | c.144G>T p.L48= | Silent (SNP) | VAF 71/394 reads (18%) | called by muse, mutect2, varscan2
- SCRIB | c.729G>C p.V243= | Silent (SNP) | VAF 27/148 reads (18%) | called by muse, mutect2, varscan2
- SDCCAG8 | c.954A>G p.A318= | Silent (SNP) | VAF 120/326 reads (37%) | catalogued as rs750272621; called by muse, varscan2
- SEC14L2 | c.627G>C p.L209= | Silent (SNP) | VAF 29/169 reads (17%) | called by muse, mutect2, varscan2
- SGCD | c.372T>A p.L124= (on ENST00000435422 / NM_001128209.2; = p.L125= on NM_000337.5) | Silent (SNP) | VAF 10/89 reads (11%) | called by muse, mutect2, varscan2
- SKIV2L | c.450T>A p.T150= | Silent (SNP) | VAF 39/211 reads (18%) | called by muse, mutect2, varscan2
- SLAIN1 | c.192G>T p.P64= | Silent (SNP) | VAF 9/43 reads (21%) | called by muse, mutect2
- SLC10A3 | c.804G>T p.G268= | Silent (SNP) | VAF 49/269 reads (18%) | called by muse, mutect2, varscan2
- SLC12A5 | c.1152C>A p.S384= (on ENST00000454036 / NM_001134771.2; = p.S361= on NM_020708.5) | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as COSV54799311, COSV54800229; called by muse, mutect2, varscan2
- SNAP91 | c.1374C>T p.A458= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs764376228, COSV52125304; called by muse, mutect2, varscan2
- TCF15 | c.244C>A p.R82= | Silent (SNP) | VAF 33/133 reads (25%) | catalogued as COSV55720354; called by muse, mutect2, varscan2
- TRPM6 | c.3348C>T p.R1116= | Silent (SNP) | VAF 12/212 reads (6%) | called by muse, mutect2
- TSPAN17 | c.168A>T p.T56= | Silent (SNP) | VAF 38/178 reads (21%) | called by muse, mutect2, varscan2
- TUBA3E | c.1117C>A p.R373= | Silent (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2, varscan2
- TULP1 | c.843C>A p.A281= | Silent (SNP) | VAF 30/148 reads (20%) | catalogued as rs1331892609; called by muse, mutect2, varscan2
- TYR | c.1503T>A p.R501= | Silent (SNP) | VAF 63/319 reads (20%) | catalogued as COSV54484537; called by muse, mutect2, varscan2
- USP17L4 | c.1179C>A p.A393= | Silent (SNP) | VAF 67/173 reads (39%) | called by muse, mutect2, varscan2
- VGLL1 | c.105G>T p.G35= | Silent (SNP) | VAF 60/284 reads (21%) | called by muse, mutect2, varscan2
- VPS13B | c.1194G>T p.T398= | Silent (SNP) | VAF 27/126 reads (21%) | catalogued as COSV62017990; called by muse, mutect2, varscan2
- WNK2 | c.3144G>T p.A1048= | Silent (SNP) | VAF 28/125 reads (22%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.1866G>T p.L622= (on ENST00000252463; = p.L677= on NM_032805.3) | Silent (SNP) | VAF 32/174 reads (18%) | catalogued as rs1169973164; called by muse, mutect2, varscan2
- ZSCAN9 | c.690A>T p.S230= | Silent (SNP) | VAF 52/307 reads (17%) | called by muse, mutect2, varscan2
- ZSWIM6 | c.582C>G p.A194= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs746876878; called by muse, mutect2
- AC024598.1 | c.981+20105T>A | Intron (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- AC073107.1 | n.1577del | RNA (DEL) | VAF 4/32 reads (13%) | called by mutect2, varscan2
- ADIG | c.*220del | 3'UTR (DEL) | VAF 56/280 reads (20%) | called by mutect2, pindel, varscan2
- AIRE | c.880-147G>T | Intron (SNP) | VAF 111/405 reads (27%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83243G>C | Intron (SNP) | VAF 28/476 reads (6%) | catalogued as rs778464065; called by muse, mutect2
- AL450442.1 | n.820G>A | RNA (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- ASMT | c.*3G>A | 3'UTR (SNP) | VAF 79/583 reads (14%) | catalogued as rs780088147; called by muse, mutect2, varscan2
- C5orf67 | n.402T>C | RNA (SNP) | VAF 12/101 reads (12%) | catalogued as rs199816445; called by muse, mutect2, varscan2
- CAPN3 | c.1782+331A>G | Intron (SNP) | VAF 55/240 reads (23%) | called by muse, mutect2, varscan2
- CASP10 | c.813+14C>T | Intron (SNP) | VAF 43/199 reads (22%) | called by muse, mutect2, varscan2
- CERS6 | c.*20C>G | 3'UTR (SNP) | VAF 26/249 reads (10%) | called by muse, mutect2, varscan2
- DRC3 | c.-7G>T | 5'UTR (SNP) | VAF 34/203 reads (17%) | catalogued as COSV100572585; called by muse, mutect2, varscan2
- ECRG4 | c.-3G>T | 5'UTR (SNP) | VAF 6/78 reads (8%) | catalogued as rs1452418485; called by muse, mutect2
- EPX | c.-36C>A | 5'UTR (SNP) | VAF 64/337 reads (19%) | called by muse, mutect2, varscan2
- FHOD3 | c.1197-5416C>T | Intron (SNP) | VAF 38/196 reads (19%) | catalogued as rs1408163485; called by muse, mutect2, varscan2
- G3BP1 | c.351+1015A>G | Intron (SNP) | VAF 42/164 reads (26%) | catalogued as rs909736420; called by muse, mutect2, varscan2
- GOT1L1 | c.116-74C>A | Intron (SNP) | VAF 26/92 reads (28%) | called by muse, mutect2
- GVINP1 | n.5002T>A | RNA (SNP) | VAF 50/216 reads (23%) | called by muse, mutect2, varscan2
- IGF2 | c.-47C>T | 5'UTR (SNP) | VAF 14/70 reads (20%) | called by muse, mutect2, varscan2
- L1CAM | c.-109+690G>T | Intron (SNP) | VAF 50/221 reads (23%) | called by muse, mutect2, varscan2
- LINC01993 | n.559C>A | RNA (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- LIPT2 | chr11:74497394 G>T | 5'Flank (SNP) | VAF 46/225 reads (20%) | catalogued as rs768453805; called by muse, mutect2, varscan2
- LMO2 | c.-272+564G>A | Intron (SNP) | VAF 37/293 reads (13%) | catalogued as rs772584017; called by muse, mutect2, varscan2
- MAGED1 | c.45+287G>A | Intron (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- MAP3K7CL | c.371-15806A>T | Intron (SNP) | VAF 31/89 reads (35%) | called by muse, mutect2, varscan2
- MEIS1 | c.743-3115G>T | Intron (SNP) | VAF 21/165 reads (13%) | called by muse, mutect2, varscan2
- MMGT1 | c.-250C>T | 5'UTR (SNP) | VAF 65/413 reads (16%) | called by muse, mutect2, varscan2
- NDUFA10 | c.999+7860G>T | Intron (SNP) | VAF 36/217 reads (17%) | called by muse, mutect2, varscan2
- NRXN1 | c.833-32781C>A | Intron (SNP) | VAF 54/173 reads (31%) | called by muse, mutect2, varscan2
- OXCT1 | c.-26G>T | 5'UTR (SNP) | VAF 26/194 reads (13%) | called by muse, mutect2, varscan2
- PKP1 | c.1295+16C>A | Intron (SNP) | VAF 36/325 reads (11%) | catalogued as rs1488751194; called by muse, mutect2, varscan2
- PSG4 | c.65-585G>T | Intron (SNP) | VAF 17/98 reads (17%) | called by muse, mutect2, varscan2
- RD3 | c.*25G>A | 3'UTR (SNP) | VAF 13/42 reads (31%) | called by muse, varscan2
- SCML2P1 | chr18:6928515 A>T | 3'Flank (SNP) | VAF 28/161 reads (17%) | called by muse, mutect2, varscan2
- SERTAD4 | c.-18+738G>A | Intron (SNP) | VAF 117/347 reads (34%) | called by muse, mutect2, varscan2
- SGK2 | c.1120-1649C>T | Intron (SNP) | VAF 23/133 reads (17%) | called by muse, mutect2, varscan2
- TFE3 | c.*4G>T | 3'UTR (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- UBE2DNL | n.536C>A | RNA (SNP) | VAF 41/169 reads (24%) | called by muse, mutect2, varscan2
- UXT | c.-10+13C>G | Intron (SNP) | VAF 44/128 reads (34%) | called by muse, mutect2, varscan2
- XIAP | c.*6442C>A | 3'UTR (SNP) | VAF 28/129 reads (22%) | called by muse, mutect2, varscan2
- ZNF638 | c.2378-2732del | Intron (DEL) | VAF 17/132 reads (13%) | called by mutect2, pindel
